Gene-level copy-number profile of tumor specimen TCGA-66-2781-01A from TCGA case TCGA-66-2781, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 67.0 years (24,471 days).
Specimen TCGA-66-2781-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ca49fc9a-cc9d-44e0-b24c-0de7ca97c36c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2781-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c6967013-21c4-4cd1-bf4e-38b15f354d2e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 2,564; copy number 2: 19,923; copy number 3: 11,962; copy number 4: 18,520; copy number 5: 3,775; copy number 6: 635; copy number 7: 699; copy number 8: 621; copy number 9: 816; copy number 10: 10; copy number 14: 117; copy number 19: 28; copy number 23: 18; copy number 27: 30; copy number 35: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2781-01A-01D-0844-01): tumor purity 0.4, ploidy 3.16, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr5:58,969,038–60,522,120, 1 gene (within-gene range 0–1): PDE4D.
- chr5:59,314,110–60,304,151, 5 genes: AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P.
- chr8:3,409,133–3,426,587, 1 gene: AC026991.2.
- chr8:4,633,065–4,635,654, 1 gene: AC022068.1.
- chr9:20,331,446–23,438,700, 71 genes (within-gene range 0–3) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,027 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,633,282–28,948,219, 12 genes, copy number 14: AC074011.1, RNA5SP89, AC092164.1, PPP1CB, SPDYA, AC097724.1, TRMT61B, WDR43, SNORD92, SNORD53, Y_RNA, SNORD53B.
- chr3:151,475,804–198,222,513, 816 genes, copy number 9 (broad region; genes not listed).
- chr8:38,269,704–38,382,272, 1 gene, copy number 35 (within-gene range 2–35): NSD3.
- chr8:38,335,981–39,417,378, 25 genes, copy number 23–35 (within-gene range 5–35): AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:39,522,976–42,405,937, 58 genes, copy number 19–27 (within-gene range 6–27): AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3.
- chr9:24,542,952–24,592,104, 2 genes, copy number 10: IZUMO3, AL353811.1.
- chr10:60,684,505–61,026,420, 6 genes, copy number 10: ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr16:26,302,064–26,358,355, 2 genes, copy number 10: AC009158.1, AC130464.1.
- chr19:39,236,433–40,950,660, 105 genes, copy number 14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
